Somatic mutation profile of tumor specimen TARGET-40-NAAWGJ-01A (aliquot TARGET-40-NAAWGJ-01A-01D) from TARGET case TARGET-40-NAAWGJ, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 17.0 years (6,205 days).
Specimen TARGET-40-NAAWGJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d33786c0-76ca-4eea-a173-c4de42bf028d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWGJ-10A (Blood Derived Normal), aliquot TARGET-40-NAAWGJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12cf35eb-151a-4f70-836d-e8dd17a24907

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP1B | c.5627-2A>T p.X1876_splice | Splice Site (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- MDN1 | c.11883A>G p.Q3961= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
